FM case AD16509 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Breast.
https://portal.gdc.cancer.gov/cases/99e81cd7-88db-42b8-bdcb-97b535815324

Female, 51.2 years: diagnosis not reported by GDC of the breast; primary biopsied or resected from the breast. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
